Somatic mutation profile of tumor specimen TCGA-B0-5711-01A (aliquot TCGA-B0-5711-01A-11D-1669-08) from TCGA case TCGA-B0-5711, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 50.5 years (18,444 days).
Specimen TCGA-B0-5711-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c2f00a6-0a29-4cb5-8e48-92b70387418f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5711-11A (Solid Tissue Normal), aliquot TCGA-B0-5711-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b4769f4-9648-4468-b731-37bb45f3de88

The open-access MAF lists 31 somatic variants for this specimen: 28 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 19, Frame Shift Del 5, Nonsense Mutation 3, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.1901A>G p.Y634C (on ENST00000272895 / NM_173076.3; = p.Y316C on NM_015657.3) | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs939160638, COSV55963029; called by muse, mutect2, varscan2
- ACP7 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.646); catalogued as COSV58699753; called by muse, mutect2, varscan2
- AMBRA1 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.874); catalogued as rs772247866, COSV54056669; called by muse, mutect2, varscan2
- COL5A2 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66410781; called by muse, mutect2, varscan2
- DLC1 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52309698; called by muse, mutect2
- ELOVL5 | c.640A>G p.I214V | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs200213620; called by muse, mutect2, varscan2
- ERG28 | c.250T>A p.F84I | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53162903; called by muse, mutect2, varscan2
- GPR75 | c.75C>G p.N25K | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.289); catalogued as COSV61828561; called by muse, mutect2, varscan2
- IGKV1-6 | c.175C>G p.Q59E | Missense Mutation (SNP) | VAF 60/241 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1225105284; called by muse, mutect2, varscan2
- IPP | c.65T>A p.L22H | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV63432868; called by muse, mutect2, varscan2
- LATS2 | c.2164G>T p.E722* | Nonsense Mutation (SNP) | VAF 68/218 reads (31%) | catalogued as COSV66876683; called by muse, mutect2, varscan2
- LGALS14 | c.413G>A p.S138N | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs528408473, COSV62372800; called by muse, mutect2, varscan2
- LIPE | c.2240A>T p.D747V | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV54923480; called by muse, mutect2, varscan2
- MCM3AP | c.5140C>A p.L1714I | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52441037; called by muse, mutect2, varscan2
- MEP1B | c.877A>T p.R293W | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV52498034; called by muse, mutect2, varscan2
- MYO5B | c.2107T>G p.F703V | Missense Mutation (SNP) | VAF 59/210 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV53221492; called by muse, mutect2, varscan2
- OR2AG1 | c.15C>A p.N5K | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56626358; called by muse, mutect2, varscan2
- PBRM1 | c.1998T>A p.Y666* | Nonsense Mutation (SNP) | VAF 57/157 reads (36%) | catalogued as COSV56282817, COSV56294012; called by muse, mutect2, varscan2
- RNMT | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.499); catalogued as COSV51085875, COSV51090089; called by muse, mutect2, varscan2
- SCAF4 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as rs953534277, COSV54588497; called by muse, mutect2, varscan2
- SMC5 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 23/103 reads (22%) | catalogued as COSV63193571; called by muse, mutect2, varscan2
- SYNJ2 | c.2236G>T p.D746Y | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62898180; called by muse, mutect2, varscan2
- VHL | c.521del p.N174Ifs*28 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | catalogued as COSV56573134; called by mutect2, pindel, varscan2
- ALDOB | c.812dup p.L271Ffs*7 | Frame Shift Ins (INS) | VAF 18/68 reads (26%) | called by mutect2, pindel, varscan2
- ATP11B | c.751_767del p.N251Wfs*11 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- FAM13A | c.500del p.L167Pfs*9 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | called by mutect2, pindel, varscan2
- NPL | c.749del p.Q250Rfs*10 | Frame Shift Del (DEL) | VAF 49/197 reads (25%) | called by mutect2, pindel, varscan2
- PEAK1 | c.2788del p.S930Afs*119 | Frame Shift Del (DEL) | VAF 29/124 reads (23%) | called by pindel, varscan2
- ICE1 | c.3030G>T p.V1010= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as COSV56827104; called by muse, mutect2, varscan2
- MEFV | c.1776C>T p.G592= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs104895161, COSV54823296; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- OR10C1 | c.57C>T p.S19= (on ENST00000622521; = p.S17= on NM_013941.3) | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV65823228; called by muse, mutect2, varscan2
